TCGA case TCGA-CN-A63T — Head and Neck Squamous Cell Carcinoma (TCGA-HNSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Larynx; Tissue source site: University of Pittsburgh. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/a3f98e70-7050-46cf-a679-ca7a83f4442f

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 60 years; Vital status: Alive.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; ICD-10 code: C32.9; Tissue or organ of origin: Larynx, NOS; Site of resection or biopsy: Head, face or neck, NOS; Classification of tumor: primary; Age at diagnosis: 60.8 years (22,201 days); Year of diagnosis: 2011; AJCC staging edition: 7th; AJCC clinical T: T3; AJCC clinical N: N2b; AJCC clinical M: M0; AJCC clinical stage: Stage IVA; AJCC pathologic T: T3; AJCC pathologic N: N2b; AJCC pathologic M: MX; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes; Extranodal extension: Microscopic Extension; Lymph nodes positive: 0; Lymph nodes tested: 80; Lymphatic invasion present: Yes; Margin status: Uninvolved; Perineural invasion present: Yes; Vascular invasion present: Yes.
   Pathology details: Lymph node dissection method: Functional (Limited) Neck Dissection; Lymph node dissection site: Neck, Right.
   Pathology details: Lymph node dissection method: Functional (Limited) Neck Dissection; Lymph node dissection site: Neck, Left.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Days to treatment start: 64 days; Days to treatment end: 64 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 64 days; Days to treatment end: 72 days; Treatment dose: 9 Gy; Treatment outcome: Complete Response; Number of fractions: 5; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Treatment intent type: Cure; Days to treatment end: 72 days; Treatment outcome: No Measurable Disease; Chemo concurrent to radiation: Yes.

Follow-up (1 entry)
- Days to follow up: 225 days; Disease response: Tumor Free.

Molecular and laboratory tests
- CDKN2A: Negative.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 46; Tobacco smoking onset year: 1965; Tobacco smoking quit year: 2011.
- Alcohol history: Yes; Alcohol drinks per day: 1.7; Alcohol days per week: 7.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-CN-A63T-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 150 mg.
  Slide TCGA-CN-A63T-01A-01-TS1: Section location: Top; Percent tumor cells: 60; Percent tumor nuclei: 60; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 40; Percent lymphocyte infiltration: 30; Percent monocyte infiltration: 20; Percent neutrophil infiltration: 30.
- Sample TCGA-CN-A63T-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-CN-A63T-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Head and Neck; Histologic diagnosis: Head & Neck Squamous Cell Carcinoma; Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; Lymph nodes examined: Yes; Lymph nodes examined IHC count: 5; Lymph node neck dissection indicator: Yes; Lymphovascular invasion: Yes; Tobacco smoking history indicator: 2; Alcohol consumption frequency: 7; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response; Tobacco smokeless use at diagnosis: No; Tobacco smokeless regular use: No; Definitive treatment method: Concurrent Chemotherapy; Definitive treatment evidence disease after: No; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 225 days; disease-specific survival: no event (censored), 225 days; progression-free interval: no event (censored), 225 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-CN-A63T-01A-11D-A28Q-01): tumor purity 0.36, ploidy 3.65, whole-genome doublings 1.
